Surgical pathology report (de-identified scan), TCGA case TCGA-91-6829, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6829-01A (Primary Tumor).

Final Pathologic Diagnosis:

BASED ON THE PERFORMED GROSS AND MICROSCOPIC EXAMINATION:

Right lung, lower lobe, lobectomy:

Poorly differentiated adenocarcinoma of bronchioloalveolar type, with high nuclear grade (3/3).

- 4.9 cm. in largest dimension.

- Pleura not involved with malignancy.

- Bronchial and vascular resection margins free of malignancy, (Frozen section diagnosis confirmed)

- Five benign peribronchial lymph nodes, no evidence of metastatic malignancy.

- No evidence of lymphovascular channel involvement.

AJCC cancer stage T2, N0, MX.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

***Electronically Signed ***

, M.D.

Intraoperative Consult Diagnosis:

Lung, right lower lobe, bronchial margin, excision:

No evidence of malignancy.

, M.D.

Gross Description:

There is one container labeled with the patient's name, " " and additionally labeled "right lower lobe, check bronchial margins". The specimen is received without fixative and consists of a lower lobe of right lung, measuring 16.4 x 10.7 x 4.6 cm. and weighing 230.0 gm. The pleura shows marked anthracosis. There is a palpable mass at approximately mid portion of the lobe, with umbilication of the overlying pleura on the lateral surface of the lobe. This umbilicated region is inked black. The bronchovascular stumps are identified in the hilar aspect. They are opened distally to reveal no intraluminal lesions. Serial sections show that the mass is 5.0 cm. from the apex of the lobe and measures 4.9 x 3.7 x 3.5 cm. It is irregularly shaped and has a tan-gray soft cut surface with necrosis and anthracotic pigment deposition. There is no gross invasion of associated bronchovascular structures. Five peribronchial lymph nodes are identified, measuring from 0.7 cm. up to 1.1 cm. All lymph nodes show severe anthracosis. The bronchial margin is shaved and submitted for frozen section. Portions of the mass and normal lung parenchyma are also submitted for tissue banking. Representative sections are submitted as follows: cassette "1" bronchial margin, for frozen section; cassette "2" vascular margins; cassettes "3" to "5" mass; cassette "6" random sections of lung; cassette "7" peribronchial lymph nodes.

Taken:

Source: NCI Genomic Data Commons file fb7401a3-63bc-4fae-bcdd-c3d89f335616 (TCGA-91-6829.D21D20D3-A384-417A-AA95-11F4B6930AF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).